Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00N, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00N-01A (Primary Tumor).

ICD-0-3

Adenocarcinoma, mucinous, NOS 8480/3

Site: Cecum C18.0

hw 3/29/11

Sample ID #:

Diagnosis:

Ileocolonic resectate under inclusion of a poorly differentiated mucinous adenocarcinoma of the colorectal type, located in the cecum/ascending colon and of max. 7.5 cm in diameter, with circumscribed penetration of the serosa. Tumor-free regional lymph nodes. Tumor-free small and large intestinal resection margins. Tumor-free mesenteric resection margin. Tumor-free omental fat tissue.

Tumor stage: pT4 pN0 (0/20) pMX; G3; L1, V0, locally R0

A further lymph node is still being decalcified; a follow-up report will be submitted at a later date.

Follow-up report:

We now have the histological data on the decalcified lymph node. In this case, there is also no indication of metastasis from the previously diagnosed carcinoma. Final tumor stage therefore pT4 pN0 (0/21) pMX; G3; L1, V0, locally R0

Source: NCI Genomic Data Commons file 510227e6-118f-498d-a27a-245229e86b45 (TCGA-AA-A00N.8A14A987-711E-49C0-AA34-2F035B02CD8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).